Somatic mutation profile of tumor specimen HTMCP-03-06-02112-01A (aliquot HTMCP-03-06-02112-01A-01D-5099) from CGCI case HTMCP-03-06-02112, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Small cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 41.5 years (15,151 days).
Specimen HTMCP-03-06-02112-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 555c5e3e-123f-45a4-a31b-b8608b8653e3.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02112-10A (Blood Derived Normal), aliquot HTMCP-03-06-02112-10A-01D-5099; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b493c45e-22b8-4b33-8ae0-458b8969af66

The open-access MAF lists 54 somatic variants for this specimen: 41 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 12, Nonsense Mutation 3, In Frame Ins 2, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 185/302 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RYR2 | c.12470G>A p.R4157Q | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.914); catalogued as rs794728786, CM097940, COSV63672629, COSV63691486; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ANKRD30B | c.3307C>T p.H1103Y | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as COSV57702636; called by muse, mutect2, varscan2
- APOB | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs1211285439; called by muse, mutect2, varscan2
- ATP13A2 | c.1399G>A p.V467M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs760443267; ClinVar: uncertain significance; called by mutect2, varscan2
- DCC | c.4270G>A p.D1424N | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV71428464, COSV71432003; called by muse, mutect2, varscan2
- DGKZ | c.1313G>A p.R438Q (on ENST00000454345 / NM_001105540.2; = p.R250Q on NM_003646.4) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.86); catalogued as rs747941646, COSV58992666; called by muse, mutect2, varscan2
- DNAH10 | c.10141G>A p.A3381T (on ENST00000409039; = p.A3320T on NM_207437.3) | Missense Mutation (SNP) | VAF 54/61 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373522460; called by muse, mutect2, varscan2
- HDAC9 | c.2047C>T p.R683* | Nonsense Mutation (SNP) | VAF 40/126 reads (32%) | catalogued as rs1201054197; called by muse, mutect2, varscan2
- LRRC9 | c.4013G>A p.R1338H | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs758764289; called by muse, mutect2, varscan2
- NLRP6 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56460561, COSV56461633; called by muse, mutect2, varscan2
- PKHD1 | c.5911G>A p.G1971S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61874814; called by mutect2, varscan2
- PPP1R9A | c.2398C>A p.L800I | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.255); catalogued as COSV56914506; called by muse, mutect2
- PRAMEF11 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs769827326, COSV70819857; called by muse, mutect2, varscan2
- RHOA | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV69041889, COSV69043206; called by muse, mutect2, varscan2
- RREB1 | c.3628G>A p.G1210R | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.383); catalogued as rs370523084; called by muse, mutect2, varscan2
- SESN2 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV53427715; called by muse, mutect2, varscan2
- STYXL2 | c.1993G>T p.A665S | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV54805047; called by muse, mutect2, varscan2
- SYCP2 | c.3280C>T p.R1094* | Nonsense Mutation (SNP) | VAF 53/220 reads (24%) | catalogued as COSV62765923, COSV62768049, COSV62771039; called by muse, mutect2, varscan2
- TNXB | c.5380G>A p.D1794N (on ENST00000647633; = p.D1547N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.311); catalogued as COSV64487749; called by muse, mutect2, varscan2
- ZFHX3 | c.2318C>T p.A773V | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs755455411, COSV51724318; called by muse, mutect2, varscan2
- ZMYM1 | c.2899A>G p.I967V | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.249); catalogued as rs189287112; called by muse, mutect2, varscan2
- ZNF257 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.199); catalogued as COSV101448176, COSV71306330; called by muse, mutect2, varscan2
- AHNAK2 | c.12704A>T p.Q4235L | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- APOB | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 56/213 reads (26%) | called by muse, mutect2, varscan2
- BRD4 | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- CABLES1 | c.1759G>T p.D587Y (on ENST00000256925 / NM_001100619.2; = p.D322Y on NM_138375.2) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDHR2 | c.2943C>G p.I981M | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- ETHE1 | c.87C>G p.F29L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- HERC2 | c.12409-4G>A | Splice Region (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- HMCN1 | c.15970_15975dup p.K5324_P5325dup | In Frame Ins (INS) | VAF 20/101 reads (20%) | called by mutect2, varscan2
- KIF15 | c.104C>G p.P35R | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP1B | c.840C>A p.F280L | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PDPR | c.2216_2218dup p.S739_R740insP | In Frame Ins (INS) | VAF 30/226 reads (13%) | called by mutect2, pindel, varscan2
- ROR2 | c.2128G>C p.V710L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLCO1B1 | c.1585G>T p.A529S | Missense Mutation (SNP) | VAF 117/129 reads (91%) | SIFT tolerated (0.4); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SSH2 | c.1440C>G p.N480K | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- TBC1D2B | c.1647G>A p.M549I | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- UBE4B | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- YME1L1 | c.1074G>C p.L358F (on ENST00000326799 / NM_139312.3; = p.L301F on NM_014263.4) | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF880 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ADGRL3 | c.4035C>T p.G1345= (on ENST00000506720 / NM_001322402.2; = p.G1234= on NM_015236.6) | Silent (SNP) | VAF 78/171 reads (46%) | catalogued as rs754794087, COSV72230382; called by muse, mutect2, varscan2
- AFF3 | c.1227C>T p.S409= | Silent (SNP) | VAF 9/11 reads (82%) | called by muse, mutect2, varscan2
- C7orf57 | c.450C>T p.F150= | Silent (SNP) | VAF 63/199 reads (32%) | catalogued as rs868833355, COSV100817332; called by muse, mutect2, varscan2
- CNTNAP4 | c.3867G>A p.L1289= | Silent (SNP) | VAF 50/380 reads (13%) | catalogued as COSV56702203; called by muse, mutect2, varscan2
- CREBBP | c.7281C>T p.V2427= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs764396354, COSV52136742; called by mutect2, varscan2
- EHD4 | c.279G>A p.P93= | Silent (SNP) | VAF 43/261 reads (16%) | catalogued as rs755750781; called by muse, mutect2, varscan2
- PLIN4 | c.1710G>A p.Q570= (on ENST00000301286; = p.Q585= on NM_001367868.2) | Silent (SNP) | VAF 48/135 reads (36%) | called by muse, mutect2, varscan2
- PRKCG | c.471C>T p.R157= | Silent (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2
- SAMD9 | c.2067G>A p.V689= | Silent (SNP) | VAF 26/280 reads (9%) | called by muse, mutect2
- THADA | c.1632C>T p.Y544= | Silent (SNP) | VAF 59/273 reads (22%) | catalogued as rs747673618, COSV100369539; called by muse, mutect2, varscan2
- UHRF1BP1 | c.90G>A p.L30= | Silent (SNP) | VAF 21/209 reads (10%) | catalogued as rs1448866270; called by muse, mutect2, varscan2
- WFS1 | c.345C>T p.G115= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs200385504, COSV99900929; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ADGRG6 | c.-7T>A | 5'UTR (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
